Somatic mutation profile of tumor specimen MP2PRT-PAVETT-TBP1-A (aliquot MP2PRT-PAVETT-TBP1-A-2-0-D-A79Q-36) from MP2PRT case MP2PRT-PAVETT, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.1 years (1,508 days).
Specimen MP2PRT-PAVETT-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 561a19cb-d3db-443f-89f6-db28bcda0c8d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVETT-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVETT-NB1-A-1-0-D-A79Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6b4e6bab-fe39-4800-af17-8328c0ec1b5d

The open-access MAF lists 17 somatic variants for this specimen: 14 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 12, Silent 3, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AVL9 | c.671T>C p.L224P | Missense Mutation (SNP) | VAF 12/294 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs1282573346, COSV59465213; called by muse, mutect2
- BTN2A1 | c.1312G>C p.D438H | Missense Mutation (SNP) | VAF 43/587 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); catalogued as COSV100438758; called by muse, mutect2
- DHX34 | c.2446G>A p.D816N | Missense Mutation (SNP) | VAF 32/725 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774448854; called by muse, mutect2
- ECM1 | c.464G>A p.R155Q | Missense Mutation (SNP) | VAF 40/586 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.045); catalogued as rs371268433; called by muse, mutect2
- NSD2 | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 34/340 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs772470710, COSV56386422; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PKD1 | c.3602C>T p.A1201V | Missense Mutation (SNP) | VAF 51/633 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.021); catalogued as rs773471530, CM143939; called by muse, mutect2
- RPGR | c.968G>A p.R323H | Missense Mutation (SNP) | VAF 11/342 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58833546; called by muse, mutect2
- TNXB | c.9824G>A p.R3275H (on ENST00000647633; = p.R3028H on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/566 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.678); catalogued as rs189416175; called by muse, mutect2
- ACTRT1 | c.86T>G p.I29S | Missense Mutation (SNP) | VAF 32/551 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0.129); called by muse, mutect2
- CSMD1 | c.4763C>G p.T1588S (on ENST00000520002; = p.T1587S on NM_033225.6) | Missense Mutation (SNP) | VAF 28/436 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.977); called by muse, mutect2
- EEA1 | c.3913G>A p.E1305K | Missense Mutation (SNP) | VAF 14/211 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); called by muse, mutect2
- EVC | c.1007G>T p.S336I | Missense Mutation (SNP) | VAF 15/400 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); called by muse, mutect2
- PML | c.34C>T p.Q12* | Nonsense Mutation (SNP) | VAF 38/562 reads (7%) | called by muse, mutect2
- ZNF683 | c.404_419del p.G135Efs*98 | Frame Shift Del (DEL) | VAF 46/533 reads (9%) | called by mutect2, pindel
- PRR12 | c.1431C>G p.L477= (on ENST00000615927; = p.L1298= on NM_020719.3) | Silent (SNP) | VAF 58/752 reads (8%) | called by muse, mutect2
- SAMSN1 | c.828C>G p.L276= (on ENST00000647101; = p.L48= on NM_001256370.1) | Silent (SNP) | VAF 26/472 reads (6%) | called by muse, mutect2
- YLPM1 | c.4773G>A p.L1591= | Silent (SNP) | VAF 39/544 reads (7%) | called by muse, mutect2
